Somatic mutation profile of tumor specimen HCM-CSHL-0727-C18-06A (aliquot HCM-CSHL-0727-C18-06A-11D-A82I-36) from HCMI case HCM-CSHL-0727-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 63.1 years (23,063 days).
Specimen HCM-CSHL-0727-C18-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1d0a3ff8-c026-47d8-8b20-3f8decd78b76.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0727-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0727-C18-10A-01D-A82I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/861fb788-ed7d-48ff-934c-d8d82be059a9

The open-access MAF lists 141 somatic variants for this specimen: 94 protein-altering or splice-affecting, 37 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 80, Silent 37, Intron 5, Nonsense Mutation 5, Frame Shift Del 3, Frame Shift Ins 3, RNA 2, Splice Site 2, 3'UTR 2, In Frame Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 175/471 reads (37%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AC099489.1 | c.8381C>T p.P2794L | Missense Mutation (SNP) | VAF 91/466 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs969670824; called by muse, mutect2, varscan2
- AGTRAP | c.233G>A p.R78Q | Missense Mutation (SNP) | VAF 105/458 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0.014); catalogued as rs766982120, COSV58668950; called by muse, mutect2, varscan2
- APC | c.3880del p.Q1294Rfs*11 | Frame Shift Del (DEL) | VAF 127/279 reads (46%) | catalogued as CD058148, CD132712, CM930027, COSV57323524; called by mutect2, pindel, varscan2
- ARHGAP22 | c.1018G>A p.V340I | Missense Mutation (SNP) | VAF 238/610 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.029); catalogued as rs755640836; called by muse, mutect2, varscan2
- ATG13 | c.1163C>T p.T388M (on ENST00000359513 / NM_001346321.1; = p.T351M on NM_014741.4 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 86/276 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.495); catalogued as rs756330086, COSV56318172; called by muse, mutect2, varscan2
- ATP6AP2 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 184/465 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.049); catalogued as rs761302416, COSV65797564; called by muse, mutect2, varscan2
- C4orf54 | c.638T>G p.L213R | Missense Mutation (SNP) | VAF 63/292 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.153); catalogued as COSV101552088, COSV72766807, COSV72767127; called by muse, mutect2, varscan2
- CACNA1F | c.1261G>A p.A421T | Missense Mutation (SNP) | VAF 143/818 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs782053409, COSV59905309; called by muse, mutect2, varscan2
- CDKN2D | c.32G>C p.R11P | Missense Mutation (SNP) | VAF 338/1021 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.866); catalogued as rs764428574; called by muse, mutect2, varscan2
- CEP126 | c.202C>T p.R68* | Nonsense Mutation (SNP) | VAF 20/188 reads (11%) | catalogued as rs757264461, COSV54822167; called by muse, mutect2, varscan2
- CNTNAP5 | c.1381C>T p.R461C | Missense Mutation (SNP) | VAF 82/468 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs752392550, COSV101443557; called by muse, mutect2, varscan2
- COL19A1 | c.346C>T p.R116W | Missense Mutation (SNP) | VAF 109/407 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1416918271, COSV59588444; called by muse, mutect2, varscan2
- CTCFL | c.1304C>A p.T435N | Missense Mutation (SNP) | VAF 34/718 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV54774329; called by muse, mutect2
- DLC1 | c.2995C>T p.R999* (on ENST00000276297 / NM_001348081.2; = p.R562* on NM_006094.5) | Nonsense Mutation (SNP) | VAF 45/287 reads (16%) | catalogued as rs774092695; called by muse, mutect2, varscan2
- DTX3 | c.571C>T p.R191W | Missense Mutation (SNP) | VAF 109/584 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV54085346; called by muse, mutect2, varscan2
- EBF3 | c.1024C>T p.R342C (on ENST00000355311 / NM_001375392.1; = p.R333C on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 108/303 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1265541353; called by muse, mutect2, varscan2
- GRB10 | c.1343C>T p.P448L (on ENST00000398812; = p.P402L on NM_001001549.3) | Missense Mutation (SNP) | VAF 62/523 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as rs373960643; called by muse, mutect2, varscan2
- HRNR | c.553G>A p.D185N | Missense Mutation (SNP) | VAF 86/461 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs140507602; called by muse, mutect2, varscan2
- IGSF1 | c.3503G>T p.W1168L | Missense Mutation (SNP) | VAF 71/535 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.174); catalogued as CM1211167; called by muse, mutect2, varscan2
- IGSF9B | c.433C>T p.P145S | Missense Mutation (SNP) | VAF 12/387 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.425); catalogued as rs994379103, COSV58063968; called by muse, mutect2
- IL11RA | c.700C>T p.R234* | Nonsense Mutation (SNP) | VAF 213/634 reads (34%) | catalogued as rs778089627; called by muse, mutect2, varscan2
- JADE1 | c.1034G>A p.R345Q | Missense Mutation (SNP) | VAF 55/246 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.584); catalogued as rs1209924861; called by muse, mutect2, varscan2
- KCNQ4 | c.806_808del p.S269del | In Frame Del (DEL) | VAF 63/325 reads (19%) | catalogued as rs797044966; called by pindel, varscan2
- LRR1 | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 30/300 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs777495090, COSV53562554; called by muse, mutect2
- NCF1 | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 47/459 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs1375017077; called by muse, mutect2, varscan2
- NIBAN1 | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 54/335 reads (16%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.938); catalogued as rs562448693, COSV62284129; called by muse, mutect2, varscan2
- NPIPB15 | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 94/562 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.01); catalogued as rs369741448, COSV70436870; called by muse, mutect2, varscan2
- NSUN4 | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 89/361 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.554); catalogued as rs761997164; called by muse, mutect2, varscan2
- NXF1 | c.1464C>A p.S488R | Missense Mutation (SNP) | VAF 44/315 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.24); catalogued as COSV53677345; called by muse, mutect2, varscan2
- OR5L1 | c.32A>C p.E11A | Missense Mutation (SNP) | VAF 79/511 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.118); catalogued as COSV100449910, COSV61732894; called by muse, mutect2, varscan2
- PANX3 | c.824C>G p.S275C | Missense Mutation (SNP) | VAF 93/500 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV52511495; called by muse, mutect2, varscan2
- PDZD4 | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 94/494 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782685044, COSV51251573; called by muse, mutect2, varscan2
- PHLPP1 | c.1601C>G p.S534C | Missense Mutation (SNP) | VAF 40/176 reads (23%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.953); catalogued as rs373755664; called by muse, mutect2, varscan2
- PKD1 | c.3595G>A p.G1199S | Missense Mutation (SNP) | VAF 267/719 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs550230113; called by muse, mutect2, varscan2
- RIMS2 | c.2117G>A p.R706H (on ENST00000666250 / NM_001348490.2; = p.R514H on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 76/201 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs754256738, COSV51679147, COSV99154333; called by muse, mutect2, varscan2
- RYR1 | c.3070C>T p.R1024C | Missense Mutation (SNP) | VAF 163/1006 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.682); catalogued as rs780121053; called by muse, mutect2, varscan2
- RYR2 | c.4829G>A p.R1610Q | Missense Mutation (SNP) | VAF 42/434 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.805); catalogued as rs764687833, COSV63719217; ClinVar: uncertain significance; called by muse, mutect2
- SETD5 | c.3313A>G p.N1105D | Missense Mutation (SNP) | VAF 114/495 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs760024950; called by muse, mutect2, varscan2
- SGSM1 | c.733G>A p.V245M | Missense Mutation (SNP) | VAF 111/448 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs768586256, COSV68509802; called by muse, mutect2, varscan2
- SMPD2 | c.857dup p.Q287Tfs*42 | Frame Shift Ins (INS) | VAF 146/649 reads (22%) | catalogued as rs763758360; called by mutect2, pindel, varscan2
- SNAP91 | c.1550C>T p.P517L | Missense Mutation (SNP) | VAF 217/706 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.121); catalogued as rs376878292, COSV52123521; called by muse, mutect2, varscan2
- SPTA1 | c.6236G>A p.R2079Q | Missense Mutation (SNP) | VAF 74/438 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.053); catalogued as rs754206036, COSV63751335, COSV63757919; called by muse, varscan2
- SURF2 | c.337+1del p.X113_splice | Splice Site (DEL) | VAF 78/467 reads (17%) | catalogued as rs1564353010; called by mutect2, pindel, varscan2
- TCF7L2 | c.1443-1G>C p.X481_splice (on ENST00000355995 / NM_001367943.1; = p.X458_splice on NM_030756.5) | Splice Site (SNP) | VAF 62/270 reads (23%) | catalogued as COSV53339516; called by mutect2, varscan2
- VEGFC | c.551C>T p.T184M | Missense Mutation (SNP) | VAF 112/222 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs554908874, COSV54594769; called by muse, mutect2, varscan2
- ZC3H3 | c.86C>T p.P29L | Missense Mutation (SNP) | VAF 114/723 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); catalogued as rs774760836, COSV99368043; called by muse, mutect2, varscan2
- ABCA12 | c.1663T>G p.L555V (on ENST00000272895 / NM_173076.3; = p.L237V on NM_015657.3) | Missense Mutation (SNP) | VAF 26/162 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- ACP7 | c.817A>G p.K273E | Missense Mutation (SNP) | VAF 156/499 reads (31%) | SIFT tolerated (0.64); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ALDH2 | c.247G>T p.A83S | Missense Mutation (SNP) | VAF 104/617 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CDH11 | c.70G>T p.A24S | Missense Mutation (SNP) | VAF 200/610 reads (33%) | SIFT tolerated (0.67); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CHML | c.511G>C p.D171H | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- COPE | c.595C>A p.Q199K | Missense Mutation (SNP) | VAF 80/566 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- DLD | c.98G>C p.R33T | Missense Mutation (SNP) | VAF 57/403 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DOCK11 | c.1811C>T p.S604L | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EBLN1 | c.388G>T p.A130S | Missense Mutation (SNP) | VAF 112/405 reads (28%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- EGR4 | c.1033G>A p.D345N (on ENST00000545030; = p.D242N on NM_001965.4) | Missense Mutation (SNP) | VAF 124/567 reads (22%) | SIFT tolerated (0.6); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- EPHA2 | c.1729T>C p.S577P | Missense Mutation (SNP) | VAF 90/416 reads (22%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- FYCO1 | c.950C>A p.T317K | Missense Mutation (SNP) | VAF 112/533 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPR37L1 | c.260C>T p.P87L | Missense Mutation (SNP) | VAF 300/812 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2
- HDAC9 | c.2810C>A p.T937K | Missense Mutation (SNP) | VAF 126/387 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- HIPK1 | c.1856del p.S619Yfs*35 | Frame Shift Del (DEL) | VAF 89/368 reads (24%) | called by mutect2, pindel, varscan2
- IRX5 | c.1436G>T p.G479V | Missense Mutation (SNP) | VAF 52/288 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KCNMA1 | c.2930C>A p.S977Y (on ENST00000286628 / NM_001161352.2; = p.S919Y on NM_002247.4) | Missense Mutation (SNP) | VAF 21/293 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.304); called by muse, mutect2
- MALRD1 | c.6112G>C p.V2038L | Missense Mutation (SNP) | VAF 14/250 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.419); called by muse, mutect2
- MAST4 | c.7040_7043del p.K2347Rfs*53 (on ENST00000403625 / NM_001164664.2; = p.K2158Rfs*53 on NM_015183.3) | Frame Shift Del (DEL) | VAF 115/786 reads (15%) | called by mutect2, pindel, varscan2
- MCMBP | c.1247C>A p.A416E | Missense Mutation (SNP) | VAF 12/206 reads (6%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.473); called by muse, mutect2
- MECOM | c.626T>C p.M209T (on ENST00000468789 / NM_001105078.4; = p.M397T on NM_004991.4) | Missense Mutation (SNP) | VAF 110/474 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- MTMR12 | c.1180G>T p.A394S | Missense Mutation (SNP) | VAF 30/294 reads (10%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- MTTP | c.2452C>T p.Q818* | Nonsense Mutation (SNP) | VAF 68/359 reads (19%) | called by muse, mutect2, varscan2
- MYO5A | c.4553G>A p.R1518Q | Missense Mutation (SNP) | VAF 56/291 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- NID2 | c.242G>A p.G81D | Missense Mutation (SNP) | VAF 161/297 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- OR2J1 | c.191T>G p.L64R | Missense Mutation (SNP) | VAF 52/226 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR4C5 | c.278G>T p.C93F | Missense Mutation (SNP) | VAF 46/363 reads (13%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR9H1P | c.547T>G p.L183V | Missense Mutation (SNP) | VAF 65/278 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); called by muse, mutect2, varscan2
- PAGE2 | c.170_171insC p.Q58Sfs*10 | Frame Shift Ins (INS) | VAF 57/339 reads (17%) | called by mutect2, pindel, varscan2
- PARP11 | c.574dup p.R192Kfs*7 | Frame Shift Ins (INS) | VAF 102/275 reads (37%) | called by mutect2, varscan2
- PCDH17 | c.667C>T p.R223C | Missense Mutation (SNP) | VAF 36/830 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- PGK2 | c.548A>G p.H183R | Missense Mutation (SNP) | VAF 128/407 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- PKD1 | c.12631G>A p.E4211K (on ENST00000262304 / NM_001009944.3; = p.E4210K on NM_000296.4) | Missense Mutation (SNP) | VAF 87/894 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.449); called by muse, mutect2
- PTH2R | c.200G>T p.W67L | Missense Mutation (SNP) | VAF 61/348 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- RAPGEF6 | c.2962G>T p.D988Y | Missense Mutation (SNP) | VAF 31/218 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RBP3 | c.2846C>A p.A949D | Missense Mutation (SNP) | VAF 105/612 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- REM1 | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 86/902 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- RGPD1 | c.1372C>A p.Q458K (on ENST00000409776; = p.Q466K on NM_001024457.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.087); called by mutect2, varscan2
- SLC8A3 | c.718T>G p.F240V | Missense Mutation (SNP) | VAF 80/373 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- SYT12 | c.230G>C p.R77T | Missense Mutation (SNP) | VAF 163/376 reads (43%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TMEM101 | c.85T>G p.W29G | Missense Mutation (SNP) | VAF 120/564 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TNS1 | c.4544A>G p.K1515R | Missense Mutation (SNP) | VAF 53/283 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TPK1 | c.5A>T p.E2V | Missense Mutation (SNP) | VAF 28/531 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.127); called by muse, mutect2
- TTN | c.35867T>G p.V11956G (on ENST00000591111; = p.V4532G on NM_003319.4) | Missense Mutation (SNP) | VAF 45/282 reads (16%) | PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- UBE3B | c.1108G>T p.V370L | Missense Mutation (SNP) | VAF 41/200 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZFC3H1 | c.1454A>T p.Y485F | Missense Mutation (SNP) | VAF 27/174 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ZNF302 | c.1382C>G p.S461* (on ENST00000627982; = p.S382* on NM_018443.3 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 15/164 reads (9%) | called by muse, mutect2
- APOL1 | c.891G>A p.P297= | Silent (SNP) | VAF 126/294 reads (43%) | catalogued as rs148496792; called by muse, varscan2
- ARL8A | c.480C>T p.Y160= | Silent (SNP) | VAF 54/367 reads (15%) | catalogued as rs922264836, COSV55343536; called by muse, mutect2, varscan2
- C20orf194 | c.783G>A p.A261= | Silent (SNP) | VAF 90/374 reads (24%) | catalogued as rs372936526; called by muse, mutect2, varscan2
- C2CD5 | c.1170A>G p.A390= | Silent (SNP) | VAF 92/260 reads (35%) | called by muse, mutect2, varscan2
- CCDC81 | c.1921C>T p.L641= (on ENST00000445632 / NM_001156474.2; = p.L551= on NM_021827.4) | Silent (SNP) | VAF 177/499 reads (35%) | called by muse, mutect2, varscan2
- CNTNAP4 | c.1680C>T p.H560= | Silent (SNP) | VAF 139/355 reads (39%) | catalogued as rs779366718; called by muse, mutect2, varscan2
- COL11A1 | c.1659T>G p.G553= | Silent (SNP) | VAF 37/313 reads (12%) | catalogued as COSV100616112; called by muse, mutect2, varscan2
- CPNE5 | c.648C>T p.H216= | Silent (SNP) | VAF 78/500 reads (16%) | catalogued as COSV55200942; called by muse, mutect2, varscan2
- EPN1 | c.471C>T p.T157= | Silent (SNP) | VAF 158/505 reads (31%) | catalogued as rs769366217, COSV99321742; called by muse, mutect2, varscan2
- EPS15 | c.477G>A p.K159= | Silent (SNP) | VAF 38/236 reads (16%) | called by muse, mutect2, varscan2
- GASK1B | c.456G>T p.P152= | Silent (SNP) | VAF 108/433 reads (25%) | catalogued as COSV56707032; called by muse, mutect2, varscan2
- ITPRID2 | c.1437T>C p.A479= | Silent (SNP) | VAF 39/273 reads (14%) | catalogued as rs986947252; called by muse, mutect2, varscan2
- LRCH2 | c.195G>A p.P65= | Silent (SNP) | VAF 52/1072 reads (5%) | called by muse, mutect2
- LRRC38 | c.237C>T p.Y79= | Silent (SNP) | VAF 124/548 reads (23%) | catalogued as rs758192768, COSV101065864; called by muse, mutect2, varscan2
- MAGED2 | c.465T>A p.P155= | Silent (SNP) | VAF 98/653 reads (15%) | called by muse, mutect2, varscan2
- MOB3A | c.360C>T p.D120= | Silent (SNP) | VAF 228/686 reads (33%) | called by muse, mutect2
- MTUS2 | c.1749G>A p.T583= | Silent (SNP) | VAF 224/962 reads (23%) | catalogued as rs757126872, COSV70917100; called by muse, mutect2, varscan2
- MYO1C | c.2979G>T p.V993= (on ENST00000648651 / NM_001080779.2; = p.V958= on NM_033375.5) | Silent (SNP) | VAF 211/414 reads (51%) | called by muse, mutect2, varscan2
- NCOA3 | c.1236G>A p.P412= | Silent (SNP) | VAF 109/1036 reads (11%) | catalogued as rs764068924; called by muse, mutect2, varscan2
- OR4A15 | c.495T>A p.P165= | Silent (SNP) | VAF 62/373 reads (17%) | catalogued as COSV100124152; called by muse, mutect2, varscan2
- PANK4 | c.2169C>T p.I723= | Silent (SNP) | VAF 179/631 reads (28%) | catalogued as rs1234065580, COSV53943592; called by muse, mutect2, varscan2
- PCDHGA4 | c.330G>A p.P110= | Silent (SNP) | VAF 70/810 reads (9%) | catalogued as rs746063927; called by muse, mutect2
- PIK3CG | c.1116C>T p.V372= | Silent (SNP) | VAF 112/670 reads (17%) | called by muse, mutect2, varscan2
- PON2 | c.49C>T p.L17= | Silent (SNP) | VAF 58/996 reads (6%) | called by muse, mutect2
- PRLHR | c.390C>T p.G130= | Silent (SNP) | VAF 169/833 reads (20%) | catalogued as COSV53303647; called by muse, mutect2, varscan2
- PXDN | c.1203C>T p.N401= | Silent (SNP) | VAF 77/494 reads (16%) | catalogued as rs1381055153, COSV53238596; ClinVar: likely benign; called by muse, mutect2, varscan2
- RXRG | c.333C>T p.D111= | Silent (SNP) | VAF 155/429 reads (36%) | called by muse, mutect2, varscan2
- SF3B2 | c.193C>T p.L65= | Silent (SNP) | VAF 95/510 reads (19%) | called by muse, mutect2, varscan2
- SFXN4 | c.396G>A p.K132= | Silent (SNP) | VAF 40/305 reads (13%) | catalogued as COSV100340987; called by muse, mutect2, varscan2
- SYT3 | c.1014C>T p.Y338= | Silent (SNP) | VAF 89/599 reads (15%) | catalogued as rs904387799, COSV104409420; called by muse, mutect2, varscan2
- TDG | c.840T>A p.P280= | Silent (SNP) | VAF 35/278 reads (13%) | called by muse, mutect2, varscan2
- TGIF2 | c.654G>A p.Q218= | Silent (SNP) | VAF 267/739 reads (36%) | called by muse, mutect2, varscan2
- THEMIS | c.1146C>T p.S382= | Silent (SNP) | VAF 222/754 reads (29%) | catalogued as rs1180503642, COSV64072401, COSV64072792; called by muse, mutect2, varscan2
- TMC1 | c.765C>A p.L255= | Silent (SNP) | VAF 37/241 reads (15%) | called by muse, mutect2, varscan2
- TOM1L2 | c.48C>T p.C16= | Silent (SNP) | VAF 115/512 reads (22%) | catalogued as rs745797143; called by muse, mutect2, varscan2
- USP42 | c.1602G>A p.Q534= | Silent (SNP) | VAF 140/413 reads (34%) | called by muse, mutect2, varscan2
- WFIKKN1 | c.816G>A p.L272= | Silent (SNP) | VAF 256/694 reads (37%) | called by muse, varscan2
- ABCD1 | c.-199G>T | 5'UTR (SNP) | VAF 129/611 reads (21%) | called by muse, mutect2, varscan2
- ARHGAP27 | c.657+130G>A | Intron (SNP) | VAF 89/442 reads (20%) | catalogued as rs767265337; called by muse, mutect2, varscan2
- BEAN1 | c.*262G>A | 3'UTR (SNP) | VAF 104/546 reads (19%) | called by muse, mutect2, varscan2
- DHX30 | c.125-2289C>G | Intron (SNP) | VAF 101/605 reads (17%) | catalogued as rs1174589727; called by muse, mutect2, varscan2
- FARP1 | c.1414+544C>A | Intron (SNP) | VAF 74/818 reads (9%) | called by muse, mutect2
- LINC01619 | n.1504G>A | RNA (SNP) | VAF 41/185 reads (22%) | called by muse, mutect2, varscan2
- LSP1 | c.53+13339C>A | Intron (SNP) | VAF 255/680 reads (38%) | called by muse, mutect2, varscan2
- MYCBP2 | c.*28G>T | 3'UTR (SNP) | VAF 63/654 reads (10%) | called by muse, mutect2
- TCP10L3 | n.2641G>A | RNA (SNP) | VAF 148/1038 reads (14%) | catalogued as rs747017426; called by muse, mutect2, varscan2
- TTN | c.34264+5293G>A | Intron (SNP) | VAF 33/304 reads (11%) | catalogued as rs1209026573, COSV60114890, COSV60160537; ClinVar: likely benign; called by muse, mutect2, varscan2
